Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7583, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7583-01A (Primary Tumor).

[page 1 of 3]
Pre-Operative/Clinical History

Left renal mass

Specimen(s) Received

A: MARGIN - BASE OF TUMOR, LEFT KIDNEY MASS
B: LEFT RENAL MASS

Gross Description

Specimen A, received fresh for frozen section labeled margin (base) of tumor, left kidney mass, consists of three friable, tan soft tissue fragments that measure 0.2 to 0.5 cm in greatest dimension. The fragments are entirely submitted for frozen section in (A1 FS [REDACTED]).

Specimen B, received in formalin labeled left renal mass, consists of a 12 gm, 4.0 x 4.0 x 2.5 cm aggregate of multiple pink, friable to papillary soft tissue fragments admixed with a small amount of adipose tissue. Representative sections are submitted in (B1-6).

Intraoperative Consultation

Specimen A, frozen section diagnosis of "neoplasm present in one of three fragments" is rendered by [REDACTED].

Microscopic Description

Sections of the first specimen reveal a fragment of adipose tissue, a fragment of benign renal parenchyma, and a single small fragment of papillary renal cell carcinoma, as described below.

Summary of Pathologic Findings Renal Carcinoma

Specimen B:

Operative procedure:

Enucleation; robotically-assisted laparoscopic left partial nephrectomy.

Tumor size:

The specimen was received morcellated and measured 4.0 x 4.0 x 2.5 cm in aggregate. Clinically, the tumor measured approximately 2.7 cm in maximum dimension.

Laterality and focality:

Left, unifocal.

Histologic type:

Papillary carcinoma, type I. (The tumor demonstrates a papillary architecture with delicate fibrovascular cores lined by small cells with low grade nuclear features. Clusters of foamy histiocytes are present within

[page 2 of 3]
HISTOLOGY REPORT

some of the cores. There is no evidence of necrosis or vascular invasion. The specimen contains small fragments of adjacent renal parenchyma.)

Sarcomatoid features: Absent.
Histologic grade: Grade I.
Extent of invasion: Cannot be determined.
Lymph/vascular invasion: Cannot be determined.
Margins: Cannot be assessed.
Adrenal gland: Not submitted.
Regional lymph nodes: Not submitted.

Special studies:

The following immunostains are performed with the tumor cells staining as follows:

Pax-8	Positive
P504S	Positive
CK7	Positive
CK20	Negative
Vimentin	Negative
CD10	Negative
TTF-1	Negative.

These immunohistochemical features are compatible with a diagnosis of papillary renal cell carcinoma

pTNM stage: The specimen was received morsellated, precluding an accurate pTNM stage. Staging in this case relies on the clinical imaging.

Pathologic findings in nonneoplastic kidney: Insufficient tissue.

Diagnosis

LEFT RENAL MASS, ROBOTICALLY-ASSISTED LAPAROSCOPIC LEFT PARTIAL NEPHRECTOMY:
LOW GRADE PAPILLARY RENAL CELL CARCINOMA.

Intradepartmental Consult

Comment

Positive and negative controls react satisfactorily.

[page 3 of 3]
HISTOLOGY REPORT

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 10d18448-2c0b-4e09-86ef-a7552a624dee (TCGA-A4-7583.5AAAA67E-F5F5-4EC0-BED2-D68541288262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).